Somatic mutation profile of tumor specimen TCGA-S9-A7R4-01A (aliquot TCGA-S9-A7R4-01A-12D-A34J-08) from TCGA case TCGA-S9-A7R4, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 46.9 years (17,134 days).
Specimen TCGA-S9-A7R4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46359501-e75b-4e86-af89-36b5ada5ef46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7R4-10A (Blood Derived Normal), aliquot TCGA-S9-A7R4-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/000dcbf6-d976-41a6-9086-1ee080ea6a55

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 33/108 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 54/77 reads (70%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYNC1I2 | c.1831T>C p.W611R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99783666; called by muse, mutect2, varscan2
- EPHA4 | c.2522A>G p.Y841C | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99915712; called by muse, mutect2, varscan2
- FCER1A | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1433078324, COSV100929236, COSV63668193; called by muse, mutect2, varscan2
- KCNJ6 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV99899220; called by muse, mutect2, varscan2
- LHFPL6 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs569393753, COSV65443393; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1993G>A p.G665S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.883); catalogued as rs752430605, COSV99151149; called by mutect2, varscan2
- MYO9A | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV61857850; called by muse, mutect2, varscan2
- NUP98 | c.5066C>G p.S1689C (on ENST00000359171 / NM_001365126.1; = p.S1672C on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV100261599, COSV100262811; called by muse, mutect2, varscan2
- OR7A17 | c.703T>A p.Y235N | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV100541574, COSV59413890; called by muse, mutect2, varscan2
- PKHD1 | c.4529C>T p.A1510V | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.595); catalogued as COSV61895047; called by muse, mutect2, varscan2
- RBM12B | c.1845G>C p.R615S | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.724); catalogued as COSV101234479; called by muse, mutect2, varscan2
- SMARCA4 | c.2356A>G p.T786A | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758192; called by muse, mutect2, varscan2
- SULT1A2 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 13/144 reads (9%) | catalogued as rs559346977, COSV100187037, COSV57680755; called by muse, mutect2
- SYNJ1 | c.2704G>A p.V902I | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs377350366; called by muse, mutect2, varscan2
- TRIM3 | c.1979G>C p.G660A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100624263, COSV100624518; called by muse, mutect2
- TUB | c.324G>C p.K108N (on ENST00000299506 / NM_177972.3; = p.K163N on NM_003320.4) | Missense Mutation (SNP) | VAF 79/271 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.981); catalogued as COSV100210045; called by muse, mutect2, varscan2
- TUB | c.427G>C p.D143H (on ENST00000299506 / NM_177972.3; = p.D198H on NM_003320.4) | Missense Mutation (SNP) | VAF 64/91 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as rs746566482, COSV100210047; called by muse, mutect2, varscan2
- ZNF217 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV56593509; called by muse, mutect2, varscan2
- YAF2 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); called by muse, varscan2
- ISL1 | c.231C>A p.I77= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100045085; called by muse, mutect2, varscan2
- MEN1 | c.1708C>T p.L570= | Silent (SNP) | VAF 27/220 reads (12%) | catalogued as COSV99580463; called by muse, mutect2, varscan2
- MS4A4A | c.93A>G p.P31= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV100557718; called by muse, mutect2, varscan2
- MYOF | c.312C>A p.I104= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV100825290; called by muse, mutect2, varscan2
- PTCHD3 | c.810C>T p.Y270= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs376677291; called by muse, mutect2, varscan2
